Surgical pathology report (de-identified scan), TCGA case TCGA-3G-AB19, project TCGA-THYM (Thymoma), tissue source site MD Anderson Cancer Center, specimen TCGA-3G-AB19-01A (Primary Tumor).

[page 1 of 3]
Accession: [REDACTED]
Specimen Date/Time:

DIAGNOSIS

- (A) THYMOMA:
INVASIVE THYMOMA EXTENDING INTO PERITHYMIC ADIPOSE TISSUES.
MAXIMUM TUMOR DIMENSION 4.5 cm.
Pericardial sac free of tumor.
- (B) ADDITIONAL PERICARDIAL MARGIN:
Pericardium negative for tumor.

Entire report and diagnosis completed by

CCF ICD-O-3
Thymoma type A, malignant 8581/3
Path *Thymoma NOS, malignant* 8580/3
Situ Thymoma 8579

GROSS DESCRIPTION

- (A) THYMOMA - Received is an 8.0 x 7.5 x 1.0 cm thymus with attached pericardium, 2.5 x 2.0 x 0.2 cm.
A 4.5 x 3.5 x 2.8 cm encapsulated mass is present, with focal areas of tan-yellow hemorrhage and calcification and a possible area of capsular invasion. The specimen is received unoriented.
SECTION CODE: A1-A3, thymoma to pericardium; A4-A6, thymoma to capsule; A7, thymoma to capsule and thymoma with area of possible capsular invasion; A8, A9, thymoma; A10, normal.
- (B) ADDITIONAL PERICARDIAL MARGIN - Received is a 4.0 x 2.0 x 0.1 cm specimen, serially sectioned and submitted in its entirety.
SECTION CODE: B1-B3, additional pericardial margin (B2 and B3 submitted on edge).

CLINICAL HISTORY

None given.

SNOMED CODES

T-D3300, M-85800

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

[page 2 of 3]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

Pew TSS dx discrepancy form,
TSSA tumor is thymoma, type A.

OK-

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Thymoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	A	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Histologic subtype was not done at initial pathologic diagnosis. Reviewing Pathologist has re-reviewed the case slide and provided the WHO subtype.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 09c16622-4198-48aa-b9fe-1a4387f60283 (TCGA-3G-AB19.99C1BFF5-733A-44EC-92D4-467771ED539D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).